Somatic mutation profile of tumor specimen C3N-01652-04 (aliquot CPT0380690009) from CPTAC case C3N-01652, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 52.1 years (19,032 days).
Specimen C3N-01652-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33932a12-f927-4181-8237-a79457ac9f42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01652-31 (Blood Derived Normal), aliquot CPT0380810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61f94b9c-16a1-4700-a83f-49248ae0def0

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 5, Silent 3, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOXA9 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 17/515 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58655957; called by muse, mutect2
- ITGAX | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs777767407, COSV51652001, COSV99192076; called by muse, mutect2, varscan2
- ZNF629 | c.2358C>G p.H786Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99354470; called by muse, mutect2, varscan2
- ATOH8 | c.383_407del p.P128Hfs*63 | Frame Shift Del (DEL) | VAF 25/146 reads (17%) | called by mutect2, pindel, varscan2
- GLIS3 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 100/348 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HELLS | c.808G>C p.V270L | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- IL4R | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.144); called by muse, varscan2
- MCHR1 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 173/447 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- MROH6 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAB1 | c.723T>A p.D241E | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO2B1 | c.814T>C p.W272R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPA1 | c.985A>C p.I329L | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- WDR87 | c.5960G>A p.G1987E | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.098); called by muse, mutect2
- ZNF404 | c.582G>C p.K194N | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF503 | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INTS12 | c.354T>A p.P118= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- ITGAD | c.528C>G p.V176= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- LAD1 | c.975G>T p.G325= | Silent (SNP) | VAF 8/8 reads (100%) | called by muse, mutect2, varscan2
- FCHO2 | c.914+826T>A | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- NECTIN1 | c.1003+532C>G | Intron (SNP) | VAF 120/375 reads (32%) | called by muse, mutect2, varscan2
- OBSCN | c.4862-16C>T | Intron (SNP) | VAF 159/270 reads (59%) | called by muse, mutect2, varscan2
- RPL4 | c.175+51G>A | Intron (SNP) | VAF 17/91 reads (19%) | catalogued as rs1220364079; called by muse, mutect2, varscan2
- STAB1 | c.2235+124T>G | Intron (SNP) | VAF 120/321 reads (37%) | called by muse, mutect2, varscan2
- TUBA4A | c.-34C>T | 5'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
